Somatic mutation profile of tumor specimen BA2953D (aliquot aq-BA2953D) from BEATAML1.0 case 2485, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.2 years (26,734 days).
Specimen BA2953D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cf0fe66-3d50-46b6-8d20-63be71a20db5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2404D (Solid Tissue Normal), aliquot aq-BA2404D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deec24f3-4644-4deb-905e-ff29cb432677

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN5 | c.451C>G p.P151A (on ENST00000456580; = p.P111A on NM_004055.5) | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- CHRD | c.2700C>A p.C900* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- PGBD5 | c.157G>C p.A53P (on ENST00000525115; = p.A122P on NM_001258311.2) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.027); called by mutect2, varscan2
- PHACTR3 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PTPRS | c.2680G>A p.G894S | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CENPI | c.480C>A p.T160= | Silent (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- OTOP2 | c.864C>A p.T288= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- PIWIL2 | c.-2C>A | 5'UTR (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100769554; called by muse, mutect2
- ZNF8 | c.66+65C>G | Intron (SNP) | VAF 31/89 reads (35%) | catalogued as rs777033411; called by muse, mutect2, varscan2
